Somatic mutation profile of tumor specimen TCGA-37-3792-01A (aliquot TCGA-37-3792-01A-01D-0983-08) from TCGA case TCGA-37-3792, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.8 years (25,502 days).
Specimen TCGA-37-3792-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa82ebe6-1205-49de-b64c-94c2bca44022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-37-3792-10A (Blood Derived Normal), aliquot TCGA-37-3792-10A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c29d0f20-773b-4bc9-b9aa-c2df657290ec

The open-access MAF lists 983 somatic variants for this specimen: 753 protein-altering or splice-affecting, 209 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 630, Silent 209, Nonsense Mutation 58, Splice Site 23, Frame Shift Del 21, Frame Shift Ins 10, Intron 10, Splice Region 10, RNA 6, 3'Flank 3, 3'UTR 2, Nonstop Mutation 1.

Variants (750 of 983; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RASA1 | c.1453+1G>T p.X485_splice | Splice Site (SNP) | VAF 24/40 reads (60%) | catalogued as rs1554047949, CD103107, COSV57194488, COSV99169911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3566G>T p.R1189L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60788908, COSV60805381; called by muse, mutect2, varscan2
- TP53 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.2877G>T p.K959N (on ENST00000272895 / NM_173076.3; = p.K641N on NM_015657.3) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.901); catalogued as COSV55965505, COSV99790205; called by muse, mutect2, varscan2
- ABCA13 | c.10567G>T p.V3523F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs776621581, COSV101446936, COSV101446979; called by mutect2, varscan2
- ABCA8 | c.4409del p.G1470Afs*8 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as COSV52201433; called by mutect2, pindel, varscan2
- ABCA9 | c.2312A>T p.N771I | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV100383142; called by muse, mutect2, varscan2
- AC024598.1 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as COSV101238068; called by muse, mutect2, varscan2
- ACACB | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs749816455, COSV100622960; called by mutect2, varscan2
- ACADM | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs774074624, COSV100897685; called by muse, mutect2, varscan2
- ACSM2B | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100312723; called by muse, mutect2, varscan2
- ACSS1 | c.935T>C p.L312P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs916831994, COSV100053772; called by muse, mutect2, varscan2
- ACTB | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs11546910, COSV100079682; called by muse, mutect2, varscan2
- ACTN4 | c.819G>A p.K273= | Splice Region (SNP) | VAF 35/89 reads (39%) | catalogued as COSV99400281; called by muse, mutect2, varscan2
- ADAM18 | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99695629; called by muse, mutect2, varscan2
- ADAM2 | c.1873G>T p.G625C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99697389; called by mutect2, varscan2
- ADAMTS1 | c.1853-2A>T p.X618_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | catalogued as COSV53171224, COSV99536190; called by muse, mutect2, varscan2
- ADAMTS12 | c.3593C>A p.P1198H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as COSV100711036; called by muse, mutect2, varscan2
- ADAMTS16 | c.2536G>T p.G846* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV56999273, COSV99941416; called by mutect2, varscan2
- ADAMTS18 | c.2149G>T p.D717Y | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99272931; called by muse, mutect2, varscan2
- ADAMTS19 | c.3103C>A p.Q1035K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as COSV99178968; called by muse, mutect2, varscan2
- ADAMTS9 | c.4196G>T p.G1399V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899518; called by muse, mutect2, varscan2
- ADAMTSL1 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99443131; called by muse, varscan2
- ADGRE1 | c.2639C>T p.P880L | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV51681262, COSV99165338; called by muse, mutect2, varscan2
- ADGRL2 | c.1808G>T p.R603M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99589387; called by muse, mutect2, varscan2
- ADGRL2 | c.2519A>C p.D840A (on ENST00000370717 / NM_001366005.1; = p.D827A on NM_012302.4) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99589388; called by muse, mutect2
- ADGRL3 | c.2197G>T p.A733S (on ENST00000506720 / NM_001322402.2; = p.A665S on NM_015236.6) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.204); catalogued as COSV101547181; called by muse, varscan2
- ADGRL3 | c.2198C>G p.A733G (on ENST00000506720 / NM_001322402.2; = p.A665G on NM_015236.6) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV101547182, COSV72231399; called by muse, varscan2
- ADH7 | c.1108G>T p.G370* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV99265283; called by muse, mutect2, varscan2
- AFDN | c.3977C>T p.S1326F | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as COSV100653059; called by muse, mutect2, varscan2
- AFF2 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 79/125 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV99664304; called by muse, mutect2, varscan2
- AFP | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99890024; called by muse, mutect2
- AGBL1 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV101408061; called by muse, mutect2, varscan2
- AGMO | c.765A>T p.E255D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100694243; called by mutect2, varscan2
- AHNAK | c.12936G>T p.W4312C | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99947718; called by muse, mutect2, varscan2
- AKNAD1 | c.1804C>A p.P602T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV100645573; called by muse, mutect2, varscan2
- ALB | c.949G>T p.V317L | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55739556; called by muse, mutect2, varscan2
- ALG10 | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.13); catalogued as rs760436672, COSV99848157; called by muse, mutect2, varscan2
- ALG8 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV100220114; called by muse, mutect2, varscan2
- AMER3 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs771745591, COSV58465229; called by muse, mutect2, varscan2
- ANKRD12 | c.3132A>T p.K1044N | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100041402; called by muse, mutect2, varscan2
- ANKRD30A | c.2086C>G p.Q696E (on ENST00000611781; = p.Q640E on NM_052997.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.184); catalogued as COSV100652704; called by mutect2, varscan2
- ANKRD34A | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100041280; called by mutect2, varscan2
- ANKRD34A | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100041278; called by muse, mutect2, varscan2
- ANKRD55 | c.1579C>A p.Q527K | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.038); catalogued as COSV100591397; called by muse, mutect2, varscan2
- ANKS1B | c.1373T>A p.M458K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100245884; called by muse, mutect2, varscan2
- ANO5 | c.1685T>C p.L562P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772361544, COSV100201902; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.2265G>C p.M755I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99265866; called by muse, mutect2, varscan2
- APOH | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 26/98 reads (27%) | catalogued as COSV52772414, COSV99235788; called by muse, mutect2, varscan2
- APP | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100695819; called by muse, mutect2, varscan2
- AQP10 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100270268; called by muse, varscan2
- AQP8 | c.458A>T p.Q153L | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99563964; called by muse, mutect2, varscan2
- ARGFX | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV100544129; called by muse, mutect2, varscan2
- ARHGAP21 | c.2358G>T p.M786I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100256258; called by muse, mutect2, varscan2
- ARMT1 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100939802; called by muse, mutect2, varscan2
- ASIC2 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.077); catalogued as COSV100726481; called by muse, mutect2
- ASTN1 | c.1736+1G>C p.X579_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99921890; called by muse, varscan2
- ASXL2 | c.2132G>T p.R711I | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV55458805, COSV99711222; called by muse, varscan2
- ATAD2B | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 26/174 reads (15%) | catalogued as COSV99477761; called by muse, mutect2, varscan2
- ATP13A1 | c.1187del p.P396Hfs*8 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV99366003; called by mutect2, pindel, varscan2
- ATP1A2 | c.1325A>T p.K442M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100767867; called by muse, mutect2, varscan2
- AXDND1 | c.2752T>A p.Y918N | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.659); catalogued as COSV100858445; called by muse, mutect2, varscan2
- BAMBI | c.541A>T p.K181* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100977504; called by muse, mutect2, varscan2
- BBS9 | c.1723G>C p.V575L (on ENST00000242067 / NM_001348036.1; = p.V535L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99628449; called by muse, mutect2, varscan2
- BBX | c.2161A>T p.K721* | Nonsense Mutation (SNP) | VAF 16/95 reads (17%) | catalogued as COSV100361658; called by muse, mutect2, varscan2
- BCAS1 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.163); catalogued as COSV101006217; called by muse, mutect2, varscan2
- BCAS2 | c.582G>T p.E194D | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.211); catalogued as COSV101058612; called by muse, mutect2, varscan2
- BCL6B | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV99546671; called by muse, mutect2, varscan2
- BCORL1 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs777232033, COSV99499693; called by muse, mutect2, varscan2
- BICC1 | c.240C>A p.I80= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100874860; called by muse, varscan2
- BICRA | c.2832G>T p.Q944H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101194342; called by muse, mutect2, varscan2
- BIRC6 | c.9337A>T p.T3113S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.234); catalogued as COSV101428337; called by muse, mutect2, varscan2
- BNC2 | c.2368C>A p.Q790K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV66155768; called by muse, mutect2, varscan2
- BNIP5 | c.1558C>A p.H520N | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); catalogued as COSV101465154; called by muse, mutect2, varscan2
- BRWD1 | c.5228C>T p.P1743L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs542494380, COSV100313514; called by muse, mutect2, varscan2
- BTAF1 | c.3126G>T p.M1042I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99795399; called by muse, varscan2
- C17orf80 | c.929A>T p.K310I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99278121; called by muse, mutect2, varscan2
- C1orf141 | c.936T>A p.N312K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.276); catalogued as COSV100924346; called by muse, varscan2
- C21orf91 | c.193T>C p.Y65H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs923416599, COSV99516046; called by muse, mutect2, varscan2
- C2CD3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs756047800, COSV100076478; called by muse, mutect2, varscan2
- C3orf56 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.563); catalogued as COSV101228960; called by muse, mutect2, varscan2
- C3orf70 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs775400044, COSV100621175; called by muse, mutect2, varscan2
- C7orf25 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs756677610, COSV100623645; called by muse, mutect2, varscan2
- CABP4 | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100351539; called by muse, mutect2, varscan2
- CACNA1C | c.4609C>T p.R1537C | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59704693; called by muse, mutect2, varscan2
- CACNA1E | c.3581C>A p.T1194K | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100702887, COSV62404131; called by muse, mutect2, varscan2
- CACNA1G | c.2545C>A p.P849T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100661892, COSV61740563; called by muse, mutect2, varscan2
- CACNA2D4 | c.2213C>G p.A738G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV99765754; called by muse, mutect2
- CACNB4 | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99138377; called by muse, mutect2, varscan2
- CADM1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522794; called by muse, mutect2, varscan2
- CADM3 | c.322T>A p.Y108N (on ENST00000368125 / NM_001127173.3; = p.Y142N on NM_021189.5) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930276, COSV100930345; called by muse, mutect2
- CADM3 | c.324C>A p.Y108* (on ENST00000368125 / NM_001127173.3; = p.Y142* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100930346; called by muse, mutect2
- CAMK4 | c.1030A>C p.S344R | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as COSV99999439; called by muse, mutect2, varscan2
- CAPN6 | c.1538A>C p.Y513S | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.186); catalogued as COSV100136894; called by muse, mutect2, varscan2
- CARD6 | c.1201T>G p.C401G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99620848; called by muse, mutect2, varscan2
- CATSPER4 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100128408; called by muse, mutect2
- CBLIF | c.1225C>A p.H409N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs762043241, COSV99950968, COSV99951045; called by muse, mutect2, varscan2
- CCDC149 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100164712; called by muse, mutect2, varscan2
- CCDC158 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1310101842, COSV101187255; called by muse, mutect2, varscan2
- CCDC198 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99371262; called by muse, mutect2, varscan2
- CCDC39 | c.2366C>A p.T789K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV56485827, COSV99869095; called by mutect2, varscan2
- CCDC63 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs778060835, COSV100370397; called by muse, varscan2
- CCPG1 | c.1688del p.R563Kfs*79 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | catalogued as COSV99380409; called by mutect2, pindel, varscan2
- CD163L1 | c.3148G>C p.E1050Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550137; called by muse, mutect2
- CD1C | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1213606010, COSV100939400; called by muse, mutect2, varscan2
- CD58 | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as COSV101043901; called by muse, mutect2, varscan2
- CD5L | c.838G>T p.V280L | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100941060; called by muse, mutect2, varscan2
- CDCA2 | c.906C>G p.D302E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.087); catalogued as COSV100398886; called by muse, mutect2, varscan2
- CDH10 | c.1091C>A p.P364Q | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV100051697; called by muse, mutect2, varscan2
- CDH12 | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV101202653; called by mutect2, varscan2
- CDH12 | c.1742G>C p.S581T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV101202654; called by muse, mutect2, varscan2
- CDH3 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770438078, COSV99868470; called by muse, mutect2, varscan2
- CDH3 | c.1909G>T p.V637L | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV99868474; called by muse, mutect2, varscan2
- CDH8 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54851181; called by muse, mutect2, varscan2
- CDHR3 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs371586125, COSV100488412; called by muse, mutect2, varscan2
- CDHR5 | c.507+1G>A p.X169_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as rs780359028, COSV99449269; called by muse, mutect2, varscan2
- CDK12 | c.3218G>C p.G1073A | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV101420464; called by muse, mutect2, varscan2
- CDK14 | c.826G>T p.G276C (on ENST00000380050 / NM_001287135.2; = p.G258C on NM_012395.3) | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56049976, COSV56057033; called by muse, mutect2, varscan2
- CDKN2AIP | c.1472T>C p.L491P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100187625; called by muse, mutect2, varscan2
- CDYL2 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101629573, COSV73647604; called by muse, mutect2
- CEACAM7 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as COSV50072534, COSV99137241; called by muse, mutect2, varscan2
- CELF2 | c.665A>G p.Q222R (on ENST00000416382 / NM_001025077.3; = p.Q229R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100257638; called by muse, mutect2, varscan2
- CEP192 | c.4987G>A p.A1663T | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.3); catalogued as COSV100381336; called by muse, mutect2, varscan2
- CEP63 | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100132784; called by muse, mutect2, varscan2
- CFAP45 | c.1247C>A p.T416K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as COSV100928590; called by muse, mutect2, varscan2
- CFAP65 | c.3629G>A p.R1210Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774403539, COSV100445329, COSV58566007; called by muse, mutect2, varscan2
- CFLAR | c.529G>T p.G177* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV100009430; called by muse, varscan2
- CHD2 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.166); catalogued as COSV101245338; called by muse, mutect2, varscan2
- CHD6 | c.3398T>A p.I1133N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100498328; called by muse, mutect2, varscan2
- CHIA | c.736G>T p.V246F (on ENST00000343320; = p.V138F on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100588693; called by muse, mutect2, varscan2
- CHIT1 | c.817C>A p.L273M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99705328; called by muse, mutect2, varscan2
- CHRM3 | c.683A>T p.E228V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as COSV99698515; called by muse, mutect2, varscan2
- CHRNA4 | c.589C>A p.R197S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.051); catalogued as COSV100937420; called by muse, mutect2, varscan2
- CHRNA4 | c.588C>A p.S196R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100937421; called by muse, mutect2, varscan2
- CHTOP | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 54/142 reads (38%) | catalogued as COSV64155010; called by muse, mutect2, varscan2
- CLEC12B | c.664G>C p.V222L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1405328613, COSV100139004; called by muse, mutect2, varscan2
- CLEC16A | c.178T>A p.W60R | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101278121; called by muse, mutect2, varscan2
- CLEC16A | c.1035G>T p.M345I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101278122; called by muse, mutect2, varscan2
- CLEC1B | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV53727086; called by muse, varscan2
- CLSTN1 | c.640G>C p.D214H (on ENST00000377298 / NM_001009566.3; = p.D204H on NM_014944.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790585; called by muse, mutect2, varscan2
- CMA1 | c.383C>G p.T128R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99157390; called by muse, mutect2, varscan2
- CMC2 | c.198G>T p.M66I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV99548233; called by muse, mutect2, varscan2
- CMKLR1 | c.670C>A p.R224S (on ENST00000312143 / NM_001142344.2; = p.R222S on NM_004072.3) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100379461; called by muse, mutect2, varscan2
- CMTR1 | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100990874, COSV100990886; called by muse, mutect2, varscan2
- CNGA2 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as rs377114471, COSV100323705, COSV100323978; called by muse, mutect2, varscan2
- CNR1 | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100759234; called by muse, mutect2, varscan2
- CNTFR | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100667561; called by muse, mutect2, varscan2
- CNTN3 | c.2299A>G p.S767G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV99724636; called by muse, mutect2, varscan2
- CNTN5 | c.1253G>T p.R418I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1283658380, COSV99677509; called by muse, mutect2, varscan2
- CNTNAP3 | c.2158C>G p.Q720E | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV99904917; called by muse, mutect2, varscan2
- CNTNAP4 | c.3562C>A p.P1188T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs540496086, COSV56702741; called by muse, mutect2, varscan2
- COL11A1 | c.4201G>C p.A1401P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100616776; called by muse, mutect2, varscan2
- COL11A1 | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62196220; called by muse, mutect2, varscan2
- COL11A1 | c.2891G>T p.G964V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616779; called by muse, mutect2, varscan2
- COL12A1 | c.7697+1G>A p.X2566_splice | Splice Site (SNP) | VAF 31/179 reads (17%) | catalogued as rs1178118885, COSV59411926; called by muse, mutect2, varscan2
- COL12A1 | c.6211-1G>A p.X2071_splice | Splice Site (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100486044, COSV59389854; called by muse, mutect2, varscan2
- COL13A1 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100637505; called by muse, mutect2, varscan2
- COL24A1 | c.3843+1G>T p.X1281_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100993440; called by muse, mutect2, varscan2
- COL6A3 | c.8023G>T p.V2675L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.176); catalogued as COSV99798574; called by muse, mutect2, varscan2
- COP1 | c.1199C>G p.T400S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.899); catalogued as COSV100443367; called by muse, mutect2, varscan2
- CORIN | c.1328G>C p.C443S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs61760497, COSV99903732; called by muse, mutect2, varscan2
- CPNE5 | c.985T>C p.F329L | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as COSV99782825; called by muse, mutect2, varscan2
- CPS1 | c.1466C>A p.P489H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99028206, COSV99243131; called by muse, mutect2, varscan2
- CR2 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV100889651, COSV100889672; called by muse, mutect2, varscan2
- CRACD | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99949386; called by muse, mutect2, varscan2
- CRB1 | c.2066A>G p.N689S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100957906; called by muse, mutect2, varscan2
- CRIM1 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV99753494, COSV99754799; called by muse, mutect2, varscan2
- CRYGN | c.106A>G p.M36V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); catalogued as rs988255218, COSV100484751; called by muse, mutect2, varscan2
- CSMD1 | c.7812G>T p.Q2604H (on ENST00000520002; = p.Q2603H on NM_033225.6) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV59411836; called by mutect2, varscan2
- CSMD3 | c.10664G>T p.R3555L (on ENST00000297405 / NM_001363185.1; = p.R3386L on NM_052900.3) | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99835790; called by muse, mutect2, varscan2
- CSRNP1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.32); catalogued as rs759270599, COSV56187438; called by mutect2, varscan2
- CST5 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100489668, COSV59014080; called by muse, mutect2, varscan2
- CST5 | c.154A>T p.I52F | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100489669, COSV59014590; called by muse, mutect2, varscan2
- CTNND2 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1398024593, COSV58866982; called by muse, mutect2
- CTSO | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.213); catalogued as COSV101467857; called by muse, mutect2, varscan2
- CTSV | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs751319414, COSV99414383; called by muse, mutect2, varscan2
- CUBN | c.6764C>A p.P2255Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as COSV64723283; called by muse, mutect2, varscan2
- CUBN | c.6763C>A p.P2255T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as COSV100912778, COSV64723148; called by muse, mutect2, varscan2
- CWF19L2 | c.1824G>T p.M608I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99979092; called by muse, mutect2, varscan2
- CXCR2 | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59280672; called by muse, mutect2, varscan2
- CYP3A7 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV100312680; called by muse, mutect2, varscan2
- CYP4A11 | c.1166T>C p.I389T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs1359618339, COSV100152419; called by muse, mutect2, varscan2
- CYP4F12 | c.545C>A p.A182D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV100215883, COSV61175863; called by muse, mutect2, varscan2
- DDX53 | c.1214T>A p.M405K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100028953; called by muse, mutect2, varscan2
- DEFB124 | c.116C>A p.T39K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100478831; called by muse, mutect2, varscan2
- DENND4A | c.1538G>A p.C513Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101475354; called by muse, mutect2, varscan2
- DGKB | c.2168C>A p.A723D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99339979; called by muse, mutect2, varscan2
- DHX30 | c.3064G>A p.G1022S (on ENST00000445061 / NM_138615.3; = p.G983S on NM_014966.3) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53137419; called by muse, mutect2, varscan2
- DIP2B | c.3167-2A>T p.X1056_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99998597; called by muse, mutect2, varscan2
- DIP2C | c.937G>C p.V313L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99791924; called by muse, mutect2, varscan2
- DIPK2B | c.1247G>T p.C416F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101211677; called by muse, mutect2, varscan2
- DLC1 | c.2873G>A p.R958Q (on ENST00000276297 / NM_001348081.2; = p.R521Q on NM_006094.5) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.209); catalogued as COSV99363371; called by muse, mutect2, varscan2
- DLC1 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV99363373; called by muse, mutect2, varscan2
- DLEC1 | c.1640C>G p.A547G | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100342499; called by muse, mutect2, varscan2
- DMBT1 | c.5011G>T p.D1671Y (on ENST00000338354 / NM_001377530.1; = p.D914Y on NM_004406.3) | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100353104; called by muse, mutect2, varscan2
- DMBT1 | c.6757A>T p.N2253Y (on ENST00000338354 / NM_001377530.1; = p.N1496Y on NM_004406.3) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV100353109; called by muse, mutect2, varscan2
- DMRT2 | c.980G>T p.S327I | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs760360224, COSV52401387, COSV52404025; called by muse, mutect2, varscan2
- DNAH2 | c.10580G>A p.R3527Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs373338819; called by muse, mutect2, varscan2
- DNAH3 | c.3960G>C p.Q1320H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as COSV99767783; called by muse, mutect2, varscan2
- DNAH5 | c.12175A>G p.I4059V | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV99450346; called by muse, mutect2, varscan2
- DNAH8 | c.1636G>T p.D546Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV59424523; called by muse, mutect2, varscan2
- DNAH9 | c.3033C>A p.S1011R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV99306091; called by muse, mutect2, varscan2
- DNAI1 | c.1146C>G p.S382R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99646859; called by muse, mutect2, varscan2
- DNAJB8 | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100048328; called by muse, varscan2
- DNAJC5B | c.117C>A p.Y39* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99395648; called by muse, mutect2, varscan2
- DOCK11 | c.5898C>G p.F1966L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353935; called by muse, mutect2, varscan2
- DOCK2 | c.2265A>T p.S755= | Splice Region (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99912799; called by muse, mutect2, varscan2
- DPF3 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs369816936, COSV100818590; called by muse, mutect2, varscan2
- DPP10 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100066397; called by muse, mutect2, varscan2
- DRD5 | c.585C>G p.N195K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV100431803; called by muse, mutect2, varscan2
- DSE | c.2789A>T p.H930L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV100528580; called by muse, mutect2, varscan2
- DSP | c.4699C>T p.Q1567* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as COSV101131312; called by muse, mutect2, varscan2
- DZIP3 | c.3382G>T p.G1128C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV100847826; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.993G>C p.Q331H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as COSV100668633; called by muse, mutect2, varscan2
- EEPD1 | c.501G>C p.E167D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV99632328; called by muse, mutect2, varscan2
- EHD3 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100434744; called by muse, mutect2, varscan2
- EID3 | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100723474; called by muse, mutect2, varscan2
- ELMO1 | c.1591C>A p.R531S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.044); catalogued as COSV100164701; called by muse, mutect2, varscan2
- ELN | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99332696; called by muse, mutect2, varscan2
- ELOA2 | c.877C>G p.R293G | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.062); catalogued as rs759103903, COSV99796779; called by muse, varscan2
- ELP4 | c.1201G>T p.D401Y (on ENST00000350638; = p.D400Y on NM_019040.5) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100635548; called by muse, mutect2, varscan2
- EPHA7 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV100992401; called by mutect2, varscan2
- EPHB6 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV67418473; called by muse, mutect2, varscan2
- ERBB4 | c.848A>T p.Y283F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV53548635, COSV99624684; called by muse, mutect2, varscan2
- ERCC2 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99676114; called by muse, mutect2
- ERICH3 | c.4247C>A p.P1416Q | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as COSV100444514; called by muse, mutect2, varscan2
- ERICH3 | c.745A>T p.R249* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100444517; called by mutect2, varscan2
- ESPL1 | c.6200G>C p.R2067P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99229383; called by muse, mutect2, varscan2
- EVC2 | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs746187559, COSV60403869; ClinVar: uncertain significance; called by mutect2, varscan2
- EVI5 | c.1012A>G p.T338A | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.777); catalogued as COSV100945330; called by muse, mutect2, varscan2
- EYA2 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as COSV100426921; called by muse, mutect2, varscan2
- FAM104B | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.967); catalogued as rs866839768, COSV100146088; called by muse, mutect2, varscan2
- FAM207A | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99384358; called by muse, mutect2, varscan2
- FBXO10 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99446795; called by muse, varscan2
- FCRL5 | c.1735G>T p.V579L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.861); catalogued as COSV100708983; called by muse, mutect2, varscan2
- FER | c.1829+1G>T p.X610_splice | Splice Site (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99811342, COSV99812962; called by muse, varscan2
- FGL2 | c.518T>G p.V173G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs772636374, COSV99592650; called by muse, mutect2, varscan2
- FIGN | c.2236G>C p.D746H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100292434; called by muse, mutect2, varscan2
- FILIP1L | c.2293G>A p.E765K (on ENST00000354552 / NM_182909.3; = p.E525K on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.957); catalogued as COSV100496891; called by muse, mutect2, varscan2
- FLII | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100493670; called by muse, mutect2, varscan2
- FMO1 | c.813A>C p.L271F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100707788; called by muse, mutect2
- FMOD | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.958); catalogued as COSV61609694; called by muse, mutect2, varscan2
- FOCAD | c.908A>T p.D303V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV100620464; called by muse, mutect2
- FOXP2 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs748314629, COSV63489989; called by muse, mutect2, varscan2
- FRMPD4 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV101043007; called by muse, mutect2, varscan2
- FSHR | c.855C>T p.I285= | Splice Region (SNP) | VAF 24/104 reads (23%) | catalogued as rs1161222069, COSV58622850; called by muse, mutect2, varscan2
- FUT10 | c.216del p.R74Efs*17 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as COSV59452481; called by mutect2, pindel, varscan2
- GABPB2 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100927235; called by muse, mutect2, varscan2
- GABRA5 | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.489); catalogued as COSV100165215; called by muse, mutect2, varscan2
- GAL3ST4 | c.1268G>C p.R423P | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.428); catalogued as COSV100385382, COSV100385498; called by muse, mutect2, varscan2
- GALNT2 | c.1314G>T p.R438S | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100795781; called by muse, mutect2, varscan2
- GAP43 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100525625, COSV59344353; called by muse, mutect2, varscan2
- GAPVD1 | c.3019G>T p.G1007W (on ENST00000394104; = p.G1034W on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.282); catalogued as COSV99783252; called by muse, mutect2, varscan2
- GBP4 | c.1306A>T p.I436F | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100864401; called by muse, mutect2, varscan2
- GCSAML | c.186T>A p.S62R | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV100825962; called by muse, mutect2, varscan2
- GEN1 | c.1409G>T p.R470L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1558411954, COSV100437991; called by muse, mutect2, varscan2
- GLG1 | c.2133G>T p.Q711H | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV99215832; called by muse, mutect2, varscan2
- GLRA3 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV99927617; called by muse, mutect2, varscan2
- GNL2 | c.1520A>C p.K507T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99953627; called by muse, mutect2, varscan2
- GOLGA3 | c.3585G>C p.V1195= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99206597; called by muse, mutect2, varscan2
- GOLGB1 | c.7799T>C p.L2600S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100510942; called by muse, mutect2, varscan2
- GORASP2 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99304580; called by muse, mutect2, varscan2
- GP2 | c.621G>T p.W207C (on ENST00000381362 / NM_001007240.3; = p.W204C on NM_001502.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100221502; called by muse, mutect2, varscan2
- GPC5 | c.1484G>T p.S495I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100993852, COSV100994220; called by muse, mutect2, varscan2
- GPR108 | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.084); catalogued as COSV99901351; called by muse, mutect2, varscan2
- GPR141 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100550346; called by muse, mutect2, varscan2
- GPR143 | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs781094686, COSV101102244, COSV66633301; called by muse, mutect2, varscan2
- GPR26 | c.900G>C p.Q300H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99500926; called by muse, mutect2, varscan2
- GPR31 | c.899T>A p.L300H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100834140; called by muse, mutect2, varscan2
- GPR34 | c.142A>T p.M48L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV100587271; called by muse, mutect2, varscan2
- GPRC6A | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV59955268; called by muse, mutect2, varscan2
- GPRIN3 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs866276732, COSV100310769; called by muse, mutect2, varscan2
- GRIA3 | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV99990348; called by muse, mutect2, varscan2
- GRIN2A | c.3875A>T p.Y1292F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100409996; called by muse, mutect2, varscan2
- GRM4 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100945824, COSV100946266; called by muse, mutect2, varscan2
- GRM8 | c.2206G>T p.A736S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as COSV58885235; called by muse, mutect2, varscan2
- GRWD1 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV99474401; called by muse, mutect2, varscan2
- GSX1 | c.714G>C p.K238N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as COSV100262561; called by muse, mutect2, varscan2
- GUCY1B1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV100025609, COSV52376734; called by muse, mutect2, varscan2
- GYS2 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV99679810; called by muse, mutect2, varscan2
- GYS2 | c.461T>C p.I154T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as COSV99679812; called by muse, mutect2, varscan2
- H3-3B | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.091); catalogued as COSV99638029; called by muse, mutect2, varscan2
- HAND1 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163980, COSV99164010; called by muse, mutect2, varscan2
- HAPLN1 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374879990, COSV57149065; called by muse, mutect2, varscan2
- HEATR5B | c.6168_6169insT p.A2057Cfs*9 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | catalogued as COSV99249422; called by mutect2, pindel, varscan2
- HEG1 | c.3677A>C p.E1226A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); catalogued as COSV100230571; called by muse, mutect2, varscan2
- HGS | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100230531; called by muse, varscan2
- HIPK3 | c.3344A>C p.Q1115P | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100305807; called by muse, mutect2, varscan2
- HMCN1 | c.5837del p.G1946Efs*22 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as COSV54907190; called by mutect2, pindel, varscan2
- HMCN1 | c.12233C>A p.P4078H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772099765, COSV99629891; called by muse, mutect2, varscan2
- HMCN1 | c.13621T>C p.C4541R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142480286; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1939G>T p.G647* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99647302; called by muse, mutect2, varscan2
- HOXA5 | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.083); catalogued as COSV99762334; called by muse, mutect2, varscan2
- HOXD3 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99980188; called by mutect2, varscan2
- ICE1 | c.5018G>T p.R1673L | Missense Mutation (SNP) | VAF 100/216 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1157878610, COSV56827796, COSV99664864; called by muse, mutect2, varscan2
- ID3 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101000770; called by muse, mutect2, varscan2
- IFNL1 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.314); catalogued as COSV100373648; called by muse, varscan2
- IFNL3 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs151331735, COSV101308017; called by muse, mutect2, varscan2
- IGDCC3 | c.1748A>T p.Q583L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as COSV100031169; called by muse, mutect2, varscan2
- IGFL2 | c.145G>T p.E49* (on ENST00000377693 / NM_001135113.2; = p.E60* on NM_001002915.2) | Nonsense Mutation (SNP) | VAF 62/194 reads (32%) | catalogued as COSV100890675; called by muse, varscan2
- IGSF1 | c.1471C>G p.H491D | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV100812106; called by muse, mutect2, varscan2
- IGSF1 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100812107; called by muse, mutect2, varscan2
- IL11RA | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as rs759020836, COSV99426505; called by muse, mutect2, varscan2
- IL25 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100198062, COSV59306076; called by muse, mutect2, varscan2
- INPPL1 | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs773871418, COSV53353158; called by mutect2, varscan2
- INTS3 | c.2482C>G p.L828V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); catalogued as COSV99669961; called by muse, mutect2, varscan2
- INTS6 | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100247093; called by muse, mutect2, varscan2
- INTS9 | c.489-1G>T p.X163_splice | Splice Site (SNP) | VAF 18/83 reads (22%) | catalogued as COSV101273883; called by muse, mutect2, varscan2
- IQGAP3 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100752164; called by muse, mutect2, varscan2
- ITGA4 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV99276392; called by muse, varscan2
- ITGB8 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99751577; called by muse, mutect2, varscan2
- ITM2B | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101052324; called by muse, mutect2, varscan2
- ITPR2 | c.3700G>T p.V1234L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.062); catalogued as COSV101190002; called by muse, mutect2, varscan2
- ITPR2 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101190003; called by muse, mutect2
- ITPRID2 | c.2379G>C p.Q793H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100238352; called by muse, mutect2, varscan2
- IZUMO2 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1387698399, COSV99518276; called by muse, mutect2, varscan2
- JCAD | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100948389, COSV100948391, COSV64758686; called by muse, mutect2, varscan2
- JMJD1C | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV101232425, COSV104434158; called by muse, mutect2, varscan2
- JPH1 | c.1323G>C p.K441N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.522); catalogued as COSV100646624; called by muse, mutect2, varscan2
- KATNAL1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV101016930; called by muse, varscan2
- KCNE4 | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99918979; called by muse, mutect2, varscan2
- KCNH5 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100526719, COSV59777552, COSV59780024; called by muse, mutect2, varscan2
- KCNQ3 | c.2103G>T p.Q701H | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV101196175; called by muse, mutect2, varscan2
- KIF1B | c.1123G>T p.E375* (on ENST00000377086 / NM_001365952.1; = p.E369* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99823423; called by muse, mutect2, varscan2
- KIF1B | c.3382G>T p.G1128* (on ENST00000377086 / NM_001365952.1; = p.G1082* on NM_015074.3) | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | catalogued as COSV99823425; called by muse, mutect2, varscan2
- KIN | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100184334; called by muse, mutect2, varscan2
- KLK6 | c.230T>A p.L77H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100037699; called by muse, mutect2, varscan2
- KLK8 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51590331, COSV99143988; called by muse, mutect2, varscan2
- KLK9 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99143989; called by muse, mutect2, varscan2
- KMT2B | c.7104G>T p.Q2368H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV99719726; called by muse, mutect2, varscan2
- KNTC1 | c.4498G>T p.E1500* | Nonsense Mutation (SNP) | VAF 33/108 reads (31%) | catalogued as COSV100338380, COSV61081735; called by muse, mutect2, varscan2
- KRT32 | c.551+1G>T p.X184_splice | Splice Site (SNP) | VAF 26/91 reads (29%) | catalogued as COSV99863045; called by muse, mutect2, varscan2
- KRT33B | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99290644; called by muse, mutect2, varscan2
- KRT82 | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99233644; called by muse, mutect2, varscan2
- KRTAP4-1 | c.202G>T p.V68F | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.622); catalogued as COSV100893538, COSV100893580; called by muse, mutect2, varscan2
- LAMA2 | c.6867+2T>G p.X2289_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | catalogued as COSV101370503; called by muse, mutect2, varscan2
- LAMA2 | c.7134G>A p.M2378I | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV101370504; called by muse, mutect2, varscan2
- LAMB1 | c.852T>A p.D284E | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99740892; called by muse, mutect2, varscan2
- LHFPL1 | c.444G>T p.M148I | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100779970; called by muse, mutect2
- LHFPL1 | c.442A>T p.M148L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100779971; called by muse, mutect2
- LILRB5 | c.1677C>A p.H559Q (on ENST00000449561 / NM_001081442.3; = p.H558Q on NM_006840.5) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100300440; called by muse, mutect2, varscan2
- LILRB5 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs774662619, COSV100300441; called by muse, mutect2, varscan2
- LIN54 | c.1229A>T p.Q410L | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV100464626; called by muse, mutect2, varscan2
- LMO7 | c.964G>A p.E322K (on ENST00000357063; = p.E337K on NM_005358.5) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100413283; called by muse, mutect2, varscan2
- LPIN1 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99877635; called by muse, mutect2, varscan2
- LPIN2 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.762); catalogued as COSV99858438; called by muse, mutect2, varscan2
- LPO | c.1648C>A p.L550M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99228877; called by muse, mutect2, varscan2
- LRCH2 | c.1426A>G p.I476V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100406912; called by muse, mutect2
- LRIF1 | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.048); catalogued as COSV100870849; called by muse, mutect2, varscan2
- LRP1B | c.12395G>T p.G4132V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as COSV101257698; called by mutect2, varscan2
- LRRC36 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV99338752; called by muse, mutect2, varscan2
- LRRC7 | c.1320G>T p.Q440H (on ENST00000651989 / NM_001370785.2; = p.Q407H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50421840, COSV50612541; called by muse, mutect2
- LRRC7 | c.2679G>C p.R893S (on ENST00000651989 / NM_001370785.2; = p.R860S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99227254; called by muse, varscan2
- LRRC7 | c.2821A>G p.R941G (on ENST00000651989 / NM_001370785.2; = p.R908G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as COSV99227256; called by muse, varscan2
- LRRC7 | c.4298C>A p.P1433Q (on ENST00000651989 / NM_001370785.2; = p.P1353Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1376546849, COSV50647126; called by muse, mutect2, varscan2
- LRRC8B | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.059); catalogued as COSV100446592, COSV58376363; called by mutect2, varscan2
- LRRK1 | c.4404C>G p.H1468Q | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99440384; called by muse, mutect2, varscan2
- LTBP2 | c.2303C>A p.A768E | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100000402; called by muse, mutect2, varscan2
- LTBP2 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100000404, COSV56211108, COSV56214780; called by muse, mutect2, varscan2
- LY6G6F | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV101011714; called by muse, mutect2, varscan2
- LY75 | c.2334G>T p.R778S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV99716508; called by muse, mutect2, varscan2
- LYPD3 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99747053; called by muse, mutect2, varscan2
- LYPD4 | c.127C>G p.H43D | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV100419417, COSV100419540, COSV58028301; called by muse, mutect2, varscan2
- MAB21L1 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV100080712, COSV100082276; called by muse, mutect2, varscan2
- MACF1 | c.16999G>A p.D5667N (on ENST00000372915; = p.D3709N on NM_012090.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99244710; called by muse, mutect2, varscan2
- MACF1 | c.18503A>T p.E6168V (on ENST00000372915; = p.E4213V on NM_012090.5) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99244712; called by muse, mutect2, varscan2
- MAGEB6 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV100983753; called by muse, varscan2
- MAGEB6 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100983754; called by muse, varscan2
- MAGEE1 | c.1500G>T p.Q500H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100819345, COSV100819407; called by muse, mutect2, varscan2
- MAP2 | c.668T>C p.L223P | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1022571526, COSV99560198; called by muse, mutect2, varscan2
- MAP3K1 | c.2119T>A p.L707M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV101266848; called by muse, mutect2, varscan2
- MAP3K19 | c.2298C>A p.D766E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV100208648; called by muse, mutect2, varscan2
- MARCHF11 | c.836T>A p.L279H | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60128645, COSV60133089; called by muse, mutect2, varscan2
- MARK1 | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100857282; called by muse, mutect2, varscan2
- MDGA2 | c.2696C>G p.P899R (on ENST00000399232 / NM_001113498.2; = p.P601R on NM_182830.4) | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV100637326, COSV100638657; called by muse, mutect2
- MDGA2 | c.976G>T p.G326* (on ENST00000399232 / NM_001113498.2; = p.G28* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100637327; called by muse, mutect2, varscan2
- MEF2B | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1052880095, COSV99364732; called by muse, mutect2, varscan2
- MIA2 | c.1100C>G p.T367S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV54485193, COSV99696783; called by muse, mutect2, varscan2
- MIOS | c.2314G>A p.V772I | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV100402800; called by muse, mutect2, varscan2
- MIP | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759746926, COSV57514663, COSV99234283; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLLT10 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100308211; called by mutect2, varscan2
- MMP16 | c.806A>T p.Q269L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99688565; called by muse, mutect2, varscan2
- MMP9 | c.1266G>A p.M422I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.133); catalogued as rs1343899909, COSV100812412, COSV63434186; called by muse, mutect2, varscan2
- MPDZ | c.1945T>C p.C649R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs776061211, COSV59941175; called by muse, mutect2, varscan2
- MRPS18B | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV99457747; called by muse, mutect2, varscan2
- MRPS27 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as rs751446042, COSV99782253; called by muse, mutect2, varscan2
- MTSS2 | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV100116544; called by muse, mutect2, varscan2
- MUC16 | c.10652C>G p.S3551* | Nonsense Mutation (SNP) | VAF 33/136 reads (24%) | catalogued as COSV101200031; called by muse, mutect2, varscan2
- MUC16 | c.10283C>G p.S3428C | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV101200032, COSV67488591; called by muse, mutect2, varscan2
- MUC5B | c.6785C>G p.T2262S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.1); catalogued as COSV101500387; called by muse, mutect2
- MUSK | c.1631T>C p.L544S | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99504392; called by muse, mutect2, varscan2
- MYBL2 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.253); catalogued as COSV99406325, COSV99406406; called by muse, mutect2, varscan2
- MYBPH | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99704543; called by muse, mutect2
- MYH11 | c.1715A>G p.K572R | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs794728678, COSV100259105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH15 | c.2758C>A p.L920M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99843378; called by muse, mutect2, varscan2
- MYOCD | c.2459T>A p.M820K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100590852; called by muse, mutect2, varscan2
- MYT1L | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.893); catalogued as rs1030359101, COSV67722120; called by muse, mutect2, varscan2
- N4BP1 | c.2224A>C p.R742= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99285220; called by muse, mutect2, varscan2
- NALCN | c.515+1G>C p.X172_splice | Splice Site (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99215488; called by muse, mutect2, varscan2
- NAV2 | c.2800C>T p.Q934* (on ENST00000396087 / NM_001244963.2; = p.Q911* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100586345; called by muse, mutect2, varscan2
- NBEAL2 | c.6110C>T p.S2037L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs763152212, COSV99436095; called by muse, mutect2, varscan2
- NCS1 | c.89+1G>A p.X30_splice | Splice Site (SNP) | VAF 16/113 reads (14%) | catalogued as COSV100969934; called by muse, mutect2, varscan2
- NDUFA12 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV100580855; called by muse, mutect2, varscan2
- NES | c.4831G>T p.G1611* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs745797630, COSV100957879; called by muse, mutect2, varscan2
- NEUROD1 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV99716943; called by muse, mutect2, varscan2
- NEUROG1 | c.396G>T p.E132D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100130806; called by mutect2, varscan2
- NEXMIF | c.1309G>T p.G437W | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99280927, COSV99281763; called by muse, mutect2, varscan2
- NF1 | c.2326-1G>T p.X776_splice | Splice Site (SNP) | VAF 35/93 reads (38%) | catalogued as COSV62191495, COSV62209539; called by muse, mutect2, varscan2
- NGRN | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as COSV100517936, COSV58961625; called by muse, mutect2, varscan2
- NHLH2 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100204991; called by muse, mutect2, varscan2
- NHS | c.1957C>A p.H653N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV101196629; called by muse, mutect2, varscan2
- NID2 | c.2394C>G p.N798K | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs757691544, COSV99356615; called by muse, mutect2, varscan2
- NKAIN3 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1180463211, COSV100133961; called by muse, mutect2, varscan2
- NLRC5 | c.2127C>A p.S709R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99347436; called by muse, mutect2, varscan2
- NLRP11 | c.216A>G p.I72M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV100789749; called by muse, mutect2, varscan2
- NLRP9 | c.1027G>T p.V343F | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as COSV100243101; called by muse, mutect2, varscan2
- NOMO3 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV99530825; called by muse, mutect2, varscan2
- NOX5 | c.1457G>C p.R486P | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as rs373021512, COSV99533975; called by muse, mutect2, varscan2
- NRG1 | c.1460G>T p.R487L (on ENST00000405005 / NM_013964.5; = p.R492L on NM_013956.5) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV55164836, COSV99828493; called by muse, mutect2, varscan2
- NRG4 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101204867; called by muse, mutect2, varscan2
- NRXN1 | c.1321G>T p.V441F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100455379; called by muse, mutect2, varscan2
- NRXN2 | c.1522C>A p.R508S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV55452927, COSV99634427; called by mutect2, varscan2
- NRXN3 | c.2555G>C p.G852A (on ENST00000335750 / NM_001330195.2; = p.G479A on NM_004796.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100204364; called by muse, mutect2, varscan2
- NTF3 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100451108; called by muse, mutect2
- NTM | c.508A>T p.R170* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV100868581; called by muse, mutect2, varscan2
- NTNG1 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637708; called by mutect2, varscan2
- NUCB1 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV99617917; called by muse, mutect2, varscan2
- OBSCN | c.12773A>T p.D4258V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99478999; called by muse, mutect2, varscan2
- OLFM3 | c.394G>C p.E132Q (on ENST00000338858 / NM_001288821.1; = p.E112Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.46); catalogued as COSV100129592, COSV100129648; called by muse, mutect2, varscan2
- OPHN1 | c.1524C>G p.V508= | Splice Region (SNP) | VAF 12/18 reads (67%) | catalogued as COSV100830486; called by muse, mutect2, varscan2
- OPRK1 | c.922G>C p.A308P | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); catalogued as COSV99653977, COSV99654109; called by muse, mutect2, varscan2
- OPRK1 | c.611-2A>G p.X204_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99654110; called by muse, mutect2, varscan2
- OR10G8 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.572); catalogued as rs1488823255, COSV101461840, COSV70908292; called by muse, mutect2, varscan2
- OR10K2 | c.775T>G p.Y259D | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149500; called by muse, mutect2, varscan2
- OR13G1 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100687295; called by muse, mutect2, varscan2
- OR1F1 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746066317, COSV100484439, COSV58961151; called by muse, mutect2, varscan2
- OR2A12 | c.885G>T p.E295D | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as COSV101283171, COSV68821740; called by muse, mutect2, varscan2
- OR2B11 | c.69C>G p.D23E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as rs145847238; called by muse, mutect2, varscan2
- OR2B2 | c.525T>G p.D175E | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100308138; called by muse, mutect2, varscan2
- OR2F2 | c.607A>T p.S203C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101283819; called by muse, mutect2, varscan2
- OR2T8 | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as rs775335952, COSV60665375; called by muse, mutect2, varscan2
- OR4C15 | c.595G>T p.G199W (on ENST00000314644; = p.G145W on NM_001001920.2) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs371985507, COSV100115723, COSV58955567; called by muse, mutect2, varscan2
- OR4D5 | c.446G>T p.W149L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100189987; called by muse, mutect2, varscan2
- OR56A4 | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100417471; called by muse, mutect2, varscan2
- OR5A1 | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100118368, COSV57375917; called by muse, mutect2, varscan2
- OR5B17 | c.828C>A p.Y276* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100641906; called by muse, mutect2, varscan2
- OR5B3 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as COSV100512005; called by muse, mutect2, varscan2
- OR5F1 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV99079670, COSV99558665; called by muse, mutect2, varscan2
- OR5T2 | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1188019468; called by muse, mutect2, varscan2
- OR6C75 | c.617T>C p.M206T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV100595347; called by muse, mutect2, varscan2
- OR8H1 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.528); catalogued as COSV100477133; called by muse, mutect2, varscan2
- OR8J1 | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV100275027; called by muse, mutect2, varscan2
- OR8J3 | c.385C>G p.P129A | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100040861; called by muse, mutect2, varscan2
- OR9G1 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1232840595, COSV100380426; called by muse, mutect2
- OSGIN2 | c.1175G>C p.C392S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99858367; called by muse, mutect2, varscan2
- OSTN | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV100174238; called by muse, mutect2, varscan2
- OTOP3 | c.1288C>G p.R430G | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV100172846; called by muse, mutect2, varscan2
- OTUD4 | c.1675G>T p.A559S (on ENST00000447906 / NM_001366057.1; = p.A494S on NM_001102653.1) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as rs775077799, COSV101485993; called by muse, mutect2, varscan2
- OVCH1 | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV100548638; called by mutect2, varscan2
- PABPC5 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as COSV100442407, COSV99058202; called by muse, mutect2, varscan2
- PACS2 | c.227G>C p.R76P | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100330782; called by muse, mutect2, varscan2
- PAG1 | c.1293G>C p.R431S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766777913, COSV99597478, COSV99598001; called by muse, mutect2, varscan2
- PAPPA2 | c.3602A>G p.D1201G | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1166115134, COSV100868235; called by muse, mutect2, varscan2
- PARD3B | c.1646A>T p.Q549L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100593641; called by muse, mutect2, varscan2
- PARP4 | c.775C>A p.L259M | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV101131677; called by muse, mutect2, varscan2
- PARS2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100988305; called by muse, mutect2, varscan2
- PATJ | c.2218G>T p.V740F | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100333708, COSV100334369; called by muse, mutect2, varscan2
- PAX4 | c.645G>T p.R215S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100490155, COSV100490301; called by muse, mutect2, varscan2
- PCDH17 | c.3326G>C p.R1109P | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); catalogued as COSV100931688, COSV64974351, COSV64977549; called by muse, mutect2, varscan2
- PCDH7 | c.2711G>A p.C904Y | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs773839320, COSV100688361, COSV62338781; called by muse, mutect2, varscan2
- PCDH8 | c.3142G>C p.G1048R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100131705; called by muse, mutect2, varscan2
- PCDHB13 | c.1050G>C p.M350I | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.005); catalogued as COSV99506568, COSV99507348; called by muse, mutect2, varscan2
- PCDHB16 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99502131; called by muse, mutect2, varscan2
- PCDHB4 | c.2250C>A p.Y750* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV99522230; called by muse, mutect2, varscan2
- PCDHGA8 | c.1948G>T p.G650C | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53913007, COSV99539177; called by muse, mutect2, varscan2
- PCLO | c.7005A>T p.L2335F | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as COSV100433255; called by muse, mutect2, varscan2
- PCNX1 | c.3703G>T p.E1235* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99455774; called by muse, mutect2, varscan2
- PCSK5 | c.3450G>T p.Q1150H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.176); catalogued as COSV101377325; called by mutect2, varscan2
- PCSK5 | c.3451G>T p.E1151* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV101377469; called by muse, mutect2, varscan2
- PCSK9 | c.1987A>G p.T663A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99599902; called by muse, mutect2, varscan2
- PDE4DIP | c.3820G>T p.D1274Y | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519520; called by muse, mutect2, varscan2
- PDE8A | c.2459A>T p.K820M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100051944; called by muse, mutect2, varscan2
- PDILT | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100199464; called by muse, mutect2, varscan2
- PDZD2 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225180; called by muse, mutect2, varscan2
- PDZRN3 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV99729926; called by muse, mutect2, varscan2
- PELI2 | c.891C>G p.N297K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99953448; called by muse, mutect2
- PGBD4 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.205); catalogued as COSV99854876; called by muse, mutect2, varscan2
- PI15 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99478049; called by muse, mutect2, varscan2
- PIGK | c.387G>C p.E129D | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100769878, COSV63061637; called by muse, mutect2, varscan2
- PIK3CD | c.2233T>C p.C745R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100740220; called by muse, mutect2
- PIP5K1C | c.1053G>T p.K351N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100095491; called by muse, mutect2, varscan2
- PIRT | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV101652676; called by muse, mutect2, varscan2
- PLA2G2F | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.027); catalogued as rs1557778692, COSV100907913; called by muse, mutect2
- PLCXD3 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.708); catalogued as COSV100125801; called by muse, mutect2, varscan2
- PLD1 | c.1341G>A p.V447= | Splice Region (SNP) | VAF 19/39 reads (49%) | catalogued as rs765996454, COSV100578203; called by muse, mutect2, varscan2
- PLD5 | c.828A>C p.K276N (on ENST00000442594; = p.K214N on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV100140639; called by muse, mutect2, varscan2
- PLOD3 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56185884, COSV99778054; called by muse, mutect2, varscan2
- PLPPR4 | c.1486G>A p.G496S | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100926807; called by muse, mutect2, varscan2
- PNPLA1 | c.1294G>T p.V432L (on ENST00000394571 / NM_001374623.1; = p.V337L on NM_173676.2) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57234731; called by muse, mutect2, varscan2
- POM121L12 | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs772646326, COSV101374922; called by muse, mutect2, varscan2
- POTEH | c.374A>T p.D125V | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as rs1303522741, COSV100624989; called by muse, varscan2
- PPFIA2 | c.3104C>T p.P1035L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100333670; called by muse, mutect2, varscan2
- PPP4R4 | c.1748G>C p.R583T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100428674, COSV58553415, COSV58559355; called by muse, mutect2, varscan2
- PRAMEF17 | c.884T>A p.L295* | Nonsense Mutation (SNP) | VAF 25/192 reads (13%) | catalogued as COSV101068735; called by muse, varscan2
- PRKCZ | c.974G>T p.R325L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101057819; called by muse, mutect2, varscan2
- PRKCZ | c.974+1G>T p.X325_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as COSV101057821; called by muse, mutect2, varscan2
- PROX1 | c.430T>A p.F144I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.266); catalogued as COSV99799512; called by muse, varscan2
- PROX1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 21/88 reads (24%) | catalogued as COSV54777862, COSV99798608, COSV99799515; called by muse, varscan2
- PRRG4 | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV99141393; called by muse, mutect2, varscan2
- PRSS37 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as COSV100633859; called by muse, mutect2, varscan2
- PSG1 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as COSV99740200; called by muse, mutect2, varscan2
- PSG11 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 96/379 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100105847; called by muse, mutect2, varscan2
- PSG4 | c.1208A>T p.K403M | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV99737150; called by muse, mutect2, varscan2
- PSMD2 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.993); catalogued as COSV100031801; called by muse, mutect2, varscan2
- PTCHD1 | c.2642T>A p.V881E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV101037731; called by muse, mutect2, varscan2
- PTCHD4 | c.1136A>T p.Y379F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV100260972; called by muse, mutect2, varscan2
- PTCRA | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.08); catalogued as COSV100485759, COSV58975905; called by muse, mutect2, varscan2
- PTPRD | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as CM153899, COSV100644988; called by muse, mutect2, varscan2
- PTPRK | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as COSV100949609; called by muse, mutect2, varscan2
- PTPRO | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99840666; called by muse, mutect2, varscan2
- PTPRT | c.4289T>C p.V1430A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100627693; called by muse, mutect2, varscan2
- PTPRT | c.1865+1G>T p.X622_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | catalogued as COSV100625964; called by muse, mutect2, varscan2
- PZP | c.2825C>A p.P942Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54367384; called by muse, mutect2, varscan2
- RABGEF1 | c.776G>T p.R259L (on ENST00000439720 / NM_001287061.2; = p.R246L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53161033; called by muse, mutect2
- RACK1 | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100958727, COSV65174687; called by muse, mutect2
- RALGAPB | c.3271G>C p.D1091H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1456915777, COSV99485309; called by muse, mutect2, varscan2
- RASAL2 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100862657; called by muse, mutect2, varscan2
- RASEF | c.1028+1G>T p.X343_splice | Splice Site (SNP) | VAF 34/71 reads (48%) | catalogued as COSV100906905; called by muse, mutect2, varscan2
- RB1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as CM961222, COSV57330277; called by muse, mutect2, varscan2
- RB1 | c.777G>T p.R259S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.573); catalogued as CD941768, COSV57305632, COSV57319048; called by muse, mutect2, varscan2
- RBBP6 | c.3070G>A p.D1024N | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs1227354611, COSV100154624; called by muse, mutect2, varscan2
- RBM38 | c.696G>C p.Q232H | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100654836; called by muse, mutect2
- RCN3 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV99571326; called by muse, mutect2, varscan2
- REV3L | c.1849T>C p.F617L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100725241; called by mutect2, varscan2
- RFPL3 | c.695C>T p.P232L (on ENST00000249007 / NM_001098535.1; = p.P203L on NM_006604.2) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs146824805; called by muse, mutect2, varscan2
- RIMS2 | c.881G>T p.R294M (on ENST00000666250 / NM_001348490.2; = p.R102M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV99169874; called by muse, mutect2, varscan2
- RIN3 | c.1664C>G p.T555R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99379345; called by muse, mutect2
- RNF145 | c.1023G>T p.L341F (on ENST00000424310 / NM_001199383.2; = p.L369F on NM_144726.2) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99193555; called by muse, mutect2, varscan2
- RNF213 | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100173516, COSV60625390; called by muse, mutect2
- RPH3A | c.916C>A p.P306T (on ENST00000389385 / NM_001143854.2; = p.P302T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV101231829; called by muse, mutect2, varscan2
- RSAD1 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV99364282; called by muse, mutect2, varscan2
- RTN2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV99838965; called by muse, mutect2, varscan2
- RUNX1 | c.556C>G p.Q186E (on ENST00000344691 / NM_001001890.3; = p.Q213E on NM_001754.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100277566; called by muse, mutect2
- RYR1 | c.9335T>A p.L3112Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.131); catalogued as COSV100615844; called by muse, mutect2, varscan2
- RYR2 | c.4445del p.R1482Pfs*13 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | catalogued as COSV63692093; called by mutect2, pindel, varscan2
- RYR2 | c.8676C>G p.I2892M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV100770313; called by muse, mutect2, varscan2
- RYR3 | c.3086C>G p.T1029S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.688); catalogued as COSV101212871; called by muse, mutect2, varscan2
- SATB1 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100113226; called by muse, mutect2
- SCN11A | c.5062G>C p.A1688P | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV56565470, COSV56572282; called by muse, mutect2, varscan2
- SCN1A | c.2592G>C p.L864= (on ENST00000303395 / NM_001202435.3; = p.L853= on NM_006920.6 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/29 reads (28%) | catalogued as rs1359762865, COSV100320603; called by muse, mutect2, varscan2
- SCN1A | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs1060502184, COSV100320606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100320612, COSV57675111; called by muse, mutect2, varscan2
- SCN2A | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99331910; called by muse, mutect2, varscan2
- SCN3A | c.5548C>A p.L1850I | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759924410, COSV99327195; called by muse, mutect2, varscan2
- SCN3A | c.2141A>T p.N714I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV99327197; called by muse, mutect2, varscan2
- SCN9A | c.1003A>T p.R335* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as rs1053777552, COSV100313009; called by muse, mutect2, varscan2
- SCP2 | c.932A>T p.N311I | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101027072; called by muse, mutect2, varscan2
- SDCCAG8 | c.1250A>T p.Q417L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV100654303; called by muse, mutect2, varscan2
- SDR42E1 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.144); catalogued as COSV100200719; called by muse, mutect2, varscan2
- SEC24D | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99756134; called by muse, mutect2, varscan2
- SECISBP2L | c.1635G>T p.L545F (on ENST00000559471 / NM_001193489.2; = p.L500F on NM_014701.4) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.034); catalogued as COSV99960412; called by muse, mutect2, varscan2
- SEMA5B | c.3413G>T p.R1138L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); catalogued as COSV52099466, COSV99531992; called by muse, varscan2
- SEMA6D | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752751517, COSV100317033; called by muse, mutect2, varscan2
- SEMA6D | c.1525C>G p.R509G | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV100317034; called by muse, mutect2, varscan2
- SEMG2 | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV101034103, COSV65647725; called by muse, mutect2, varscan2
- SERPINB11 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV101236248; called by muse, mutect2, varscan2
- SESTD1 | c.415T>C p.C139R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100090550; called by muse, mutect2, varscan2
- SFXN1 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.516); catalogued as COSV100369337, COSV58493281; called by muse, mutect2, varscan2
- SIGLEC5 | c.1632C>A p.Y544* | Nonsense Mutation (SNP) | VAF 22/86 reads (26%) | catalogued as COSV99707535; called by muse, mutect2, varscan2
- SLC12A7 | c.2336A>T p.Q779L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99369977; called by muse, mutect2, varscan2
- SLC17A6 | c.1087G>C p.V363L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV99581540; called by muse, mutect2, varscan2
- SLC22A15 | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV101047803; called by muse, mutect2, varscan2
- SLC22A25 | c.403-1G>C p.X135_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100123639; called by muse, mutect2
- SLC22A9 | c.1436T>A p.I479K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.702); catalogued as COSV99655045; called by muse, mutect2, varscan2
- SLC24A2 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99646750; called by muse, mutect2, varscan2
- SLC2A2 | c.767C>G p.A256G | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049353; called by muse, mutect2, varscan2
- SLC2A3 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50002798, COSV99306643; called by muse, mutect2, varscan2
- SLC34A3 | c.497G>C p.G166A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100746668; called by muse, mutect2, varscan2
- SLC35F3 | c.259G>A p.A87T (on ENST00000366617 / NM_001300845.1; = p.A156T on NM_173508.4) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV64020985; called by muse, mutect2, varscan2
- SLC41A3 | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV100259637; called by muse, mutect2, varscan2
- SLC46A2 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.026); catalogued as rs752268211, COSV65290262; called by muse, mutect2, varscan2
- SLC4A1AP | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as COSV100389405; called by muse, mutect2, varscan2
- SLC4A4 | c.2452G>T p.G818W (on ENST00000264485 / NM_001098484.3; = p.G774W on NM_003759.4) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140320; called by muse, mutect2, varscan2
- SLC5A8 | c.1661A>T p.Y554F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101610559; called by muse, mutect2, varscan2
- SLC5A9 | c.368G>C p.W123S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361697; called by muse, mutect2, varscan2
- SLC6A4 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99911397; called by muse, mutect2, varscan2
- SLC7A13 | c.32G>C p.R11T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99878928; called by muse, mutect2
- SLCO1B1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99918570; called by muse, mutect2, varscan2
- SLCO1B3 | c.1866A>T p.G622= | Splice Region (SNP) | VAF 14/23 reads (61%) | catalogued as COSV99681532; called by muse, mutect2, varscan2
- SLIT1 | c.3707A>G p.Y1236C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99821500; called by muse, mutect2, varscan2
- SNCA | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs918531737, COSV100409967; called by muse, mutect2, varscan2
- SNX14 | c.2203C>T p.P735S (on ENST00000314673 / NM_001350535.1; = p.P682S on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.89); catalogued as COSV100121575; called by muse, mutect2, varscan2
- SNX14 | c.1739C>T p.S580F (on ENST00000314673 / NM_001350535.1; = p.S527F on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100121577; called by muse, mutect2, varscan2
- SOAT1 | c.497+2T>C p.X166_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV62653947; called by muse, mutect2
- SOS2 | c.696A>T p.R232S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99366189; called by muse, mutect2, varscan2
- SOX5 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100507043; called by muse, mutect2, varscan2
- SPAG17 | c.3828G>T p.M1276I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100309254; called by muse, mutect2, varscan2
- SPAG17 | c.2242G>C p.A748P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100309256; called by muse, mutect2, varscan2
- SPANXN2 | c.96C>G p.N32K | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.499); catalogued as COSV100979903, COSV65127719, COSV65128143; called by muse, mutect2, varscan2
- SPATA16 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.352); catalogued as COSV100651304; called by muse, mutect2
- SPATA19 | c.461C>G p.S154* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100141112; called by muse, mutect2, varscan2
- SPG11 | c.3146-1G>C p.X1049_splice | Splice Site (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99968774; called by muse, mutect2
- SPON1 | c.2111C>A p.A704E | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100115959; called by muse, mutect2, varscan2
- SPTBN1 | c.2263G>C p.D755H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100442717, COSV61685395; called by muse, mutect2, varscan2
- SSBP3 | c.1157T>A p.M386K (on ENST00000371320 / NM_145716.4; = p.M366K on NM_018070.5) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.493); catalogued as COSV100486439; called by muse, mutect2, varscan2
- STOX1 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100057905; called by muse, mutect2, varscan2
- STRC | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.853); catalogued as rs1451645577, COSV101405424; called by muse, mutect2, varscan2
- STX3 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100275939; called by muse, mutect2, varscan2
- STXBP5L | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV99874491; called by muse, mutect2
- STXBP5L | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99874493; called by muse, mutect2, varscan2
- SULF1 | c.2088G>C p.K696N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV99483180; called by muse, mutect2, varscan2
- SVEP1 | c.914G>T p.C305F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100238136; called by muse, mutect2, varscan2
- SYNC | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV100995323; called by muse, mutect2, varscan2
- SYNDIG1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100965286; called by muse, mutect2, varscan2
- TAF1L | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99644772; called by muse, mutect2, varscan2
- TAS2R39 | c.350T>A p.F117Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.111); catalogued as COSV101489405; called by muse, mutect2, varscan2
- TBC1D10B | c.1167G>C p.E389D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV101329637; called by muse, mutect2, varscan2
- TBX10 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100039752; called by muse, mutect2
- TBX4 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1190455094, COSV99540304; called by muse, mutect2, varscan2
- TCF7L1 | c.1350G>T p.K450N | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV99964425; called by muse, mutect2, varscan2
- TCTE1 | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs770246526, COSV101025449; called by muse, mutect2, varscan2
- TDG | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV99904197; called by muse, mutect2, varscan2
- TDRD3 | c.862+1G>C p.X288_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99540490; called by muse, mutect2, varscan2
- TDRD9 | c.3133A>G p.T1045A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1032191747, COSV100175190; called by muse, mutect2, varscan2
- TENM2 | c.2673G>T p.Q891H (on ENST00000518659 / NM_001122679.2; = p.Q659H on NM_001080428.3) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV101318818; called by muse, mutect2, varscan2
- TENT4A | c.1418A>T p.Y473F | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100048995; called by muse, mutect2, varscan2
- TESPA1 | c.1342A>G p.M448V (on ENST00000316577 / NM_001098815.3; = p.M310V on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100345283; called by muse, mutect2, varscan2
- TEX55 | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1173641903, COSV99817549; called by muse, mutect2, varscan2
- TFAP2D | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50421392; called by muse, mutect2, varscan2
- TG | c.8078G>C p.G2693A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as COSV99601089; called by muse, mutect2, varscan2
- THPO | c.937G>C p.V313L (on ENST00000649095 / NM_001290003.1; = p.V173L on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as COSV99201157, COSV99201194; called by muse, mutect2, varscan2
- THSD7B | c.1754T>A p.V585D | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV99751909; called by mutect2, varscan2
- TLL2 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100780312; called by muse, mutect2, varscan2
- TMEM131 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV51781078, COSV99487894; called by mutect2, varscan2
- TMEM177 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV99733628; called by muse, mutect2, varscan2
- TMEM200C | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.046); catalogued as COSV101274836; called by muse, mutect2, varscan2
- TMEM255B | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.784); catalogued as COSV100943199; called by muse, mutect2, varscan2
- TMTC1 | c.327G>A p.M109I (on ENST00000539277 / NM_001193451.2; = p.M1? on NM_175861.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as rs773863525, COSV99759767; called by mutect2, varscan2
- TMTC2 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV100338096; called by muse, mutect2, varscan2
- TNFRSF14 | c.611G>T p.W204L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.641); catalogued as COSV100859159; called by muse, mutect2, varscan2
- TNMD | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100887864; called by muse, mutect2, varscan2
- TNN | c.3413A>T p.K1138M | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as rs867243475, COSV99512079; called by muse, mutect2, varscan2
- TNNI3 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV99402881; called by muse, mutect2, varscan2
- TNNI3K | c.2350A>G p.S784G | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99631646; called by muse, mutect2, varscan2
- TPTE | c.692C>A p.T231K (on ENST00000618007 / NM_199261.4; = p.T213K on NM_199259.4) | Missense Mutation (SNP) | VAF 131/359 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1185018439; called by muse, mutect2, varscan2
- TREM2 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100632621; called by muse, mutect2, varscan2
- TRHDE | c.1603A>T p.R535* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV53860457, COSV99671022; called by muse, mutect2, varscan2
- TRIM42 | c.1928C>T p.S643F | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.091); catalogued as COSV99648408, COSV99648826; called by muse, mutect2, varscan2
- TRIM59 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV100557506; called by muse, mutect2, varscan2
- TRIM60 | c.146A>T p.D49V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.445); catalogued as rs1017047320, COSV100594028; called by muse, mutect2, varscan2
- TRIML2 | c.1308C>A p.S436R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.066); catalogued as COSV100456090; called by muse, mutect2, varscan2
- TRIO | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV100710428, COSV60083125; called by muse, mutect2, varscan2
- TRPA1 | c.1814G>A p.W605* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100084279; called by muse, mutect2, varscan2
- TRPC7 | c.1254C>A p.N418K | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.491); catalogued as rs377216472, COSV100725735; called by muse, mutect2, varscan2
- TRPM1 | c.2774G>C p.G925A | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as COSV99856009; called by muse, mutect2, varscan2
- TRPM8 | c.2869A>G p.I957V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.97); catalogued as COSV100224114; called by muse, varscan2
- TRPS1 | c.2754C>A p.N918K (on ENST00000220888 / NM_001330599.2; = p.N931K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99631270; called by muse, mutect2, varscan2
- TSHZ2 | c.2441C>G p.S814C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100296168; called by muse, mutect2, varscan2
- TSHZ3 | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99551752; called by muse, mutect2, varscan2
- TSNARE1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV100210692; called by muse, mutect2
- TSNARE1 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100210693; called by muse, mutect2
- TSNAX | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV100791110; called by muse, mutect2, varscan2
- TTN | c.65144T>A p.V21715D (on ENST00000591111; = p.V14291D on NM_003319.4) | Missense Mutation (SNP) | VAF 33/101 reads (33%) | PolyPhen possibly damaging (0.885); catalogued as COSV100615450; called by muse, mutect2, varscan2
- TTN | c.59833G>T p.E19945* (on ENST00000591111; = p.E12521* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 36/112 reads (32%) | catalogued as COSV100615452; called by muse, mutect2, varscan2
- TTN | c.40929C>A p.H13643Q (on ENST00000591111; = p.H6219Q on NM_003319.4) | Missense Mutation (SNP) | VAF 37/132 reads (28%) | PolyPhen benign (0); catalogued as COSV100615455; called by muse, mutect2, varscan2
- TXLNB | c.1907C>A p.A636E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.015); catalogued as COSV100624990; called by muse, mutect2, varscan2
- U2AF2 | c.1229G>C p.G410A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100454275; called by muse, mutect2, varscan2
- U2SURP | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs758588508, COSV101204497; called by mutect2, varscan2
- UBE4B | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99036810; called by muse, mutect2, varscan2
- UBE4B | c.3815G>T p.R1272L (on ENST00000343090 / NM_001105562.3; = p.R1143L on NM_006048.5) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53535741, COSV99476739; called by muse, mutect2, varscan2
- UBQLN1 | c.272T>G p.L91W | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99973385; called by muse, mutect2, varscan2
- UBR1 | c.3391G>T p.G1131* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99317297; called by muse, varscan2
- UGGT2 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV100948709; called by muse, mutect2, varscan2
- UGT1A5 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs369417360, COSV59397276; called by muse, mutect2, varscan2
- UNC5D | c.764G>C p.W255S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV99775711; called by muse, mutect2, varscan2
- USP18 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs774930317, COSV99306110; called by muse, mutect2, varscan2
- USP9X | c.7537C>T p.P2513S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100199365; called by muse, mutect2, varscan2
- UTP14C | c.539G>T p.R180I | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101584306; called by muse, mutect2, varscan2
- VAC14 | c.191A>T p.Q64L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV55752239, COSV99934668; called by muse, mutect2, varscan2
- VASP | c.247C>G p.R83G | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99841018; called by muse, mutect2, varscan2
- VAV3 | c.1954A>C p.S652R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.71); catalogued as COSV100579838; called by muse, mutect2, varscan2
- VCAM1 | c.2218T>C p.*740Qext*30 | Nonstop Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99658582; called by mutect2, varscan2
- VNN2 | c.1014G>T p.R338S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV100426798; called by muse, mutect2, varscan2
- VPS51 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV99659666; called by muse, mutect2, varscan2
- VSIG10 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs192104873; called by muse, mutect2, varscan2
- WASHC3 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV99527518; called by muse, mutect2, varscan2
- WDFY3 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV99883738; called by muse, mutect2, varscan2
- WNT7A | c.792G>A p.M264I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV99541372; called by muse, mutect2, varscan2
- WSB1 | c.593G>T p.W198L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99286035; called by muse, mutect2, varscan2
- XIRP2 | c.508C>A p.Q170K (on ENST00000628543; = p.Q345K on NM_152381.6) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs1329024194, COSV54697810, COSV99743438; called by muse, mutect2, varscan2
- YTHDF3 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV101572393; called by muse, mutect2, varscan2
- ZCCHC17 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201721345, COSV60003482; called by muse, mutect2, varscan2
- ZEB2 | c.1676T>C p.L559P | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100356133; called by muse, mutect2, varscan2
- ZFHX3 | c.3347A>T p.E1116V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99212848; called by muse, mutect2, varscan2
- ZFHX3 | c.3346G>T p.E1116* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV51715995, COSV99212853; called by muse, mutect2, varscan2
- ZIM2 | c.633C>A p.N211K | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99689152; called by muse, mutect2, varscan2
- ZMYM4 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV100110632; called by muse, mutect2
- ZNF202 | c.1923G>T p.R641S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100279059; called by muse, mutect2, varscan2
- ZNF226 | c.1580G>T p.G527V | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100335156; called by muse, mutect2, varscan2
- ZNF235 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.459); catalogued as COSV52156167, COSV99349490; called by muse, mutect2, varscan2
- ZNF318 | c.4529C>T p.P1510L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100546212; called by muse, mutect2, varscan2
- ZNF33A | c.309G>T p.W103C (on ENST00000458705 / NM_006974.3; = p.W104C on NM_006954.2) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100275846; called by muse, mutect2, varscan2
- ZNF347 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as COSV100498036, COSV100498306; called by muse, mutect2, varscan2
- ZNF383 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100776761; called by muse, mutect2, varscan2
- ZNF436 | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.749); catalogued as COSV100011094; called by muse, mutect2, varscan2
- ZNF493 | c.1897A>G p.I633V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1436805115, COSV62753480; called by muse, mutect2, varscan2
- ZNF644 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100494511; called by muse, mutect2, varscan2
- ZNF677 | c.751A>G p.T251A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100447968; called by muse, mutect2, varscan2
- ZNF91 | c.789G>T p.E263D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV56083655; called by muse, mutect2, varscan2
- ZP4 | c.1164C>A p.C388* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100850690; called by muse, mutect2, varscan2
- ZP4 | c.107del p.P36Rfs*8 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV63912911, COSV99053321; called by mutect2, pindel, varscan2
- ACACB | c.1140G>T p.W380C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- ADAM29 | c.51dup p.G18Wfs*6 | Frame Shift Ins (INS) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- APOB | c.9682del p.I3228Lfs*38 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- ARFGEF1 | c.504dup p.G169Rfs*74 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel
- ARMC4 | c.1661dup p.L554Ffs*13 | Frame Shift Ins (INS) | VAF 5/21 reads (24%) | called by mutect2, pindel, varscan2
- ATN1 | c.1995C>A p.F665L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- C5AR2 | c.507del p.A170Pfs*31 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- CT45A1 | c.111_112insC p.R38Qfs*37 | Frame Shift Ins (INS) | VAF 38/243 reads (16%) | called by mutect2, pindel, varscan2
- FAM167B | c.197del p.G66Dfs*46 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
- FRMPD4 | c.281del p.G94Afs*11 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- FSCB | c.1226del p.P409Qfs*4 | Frame Shift Del (DEL) | VAF 10/73 reads (14%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1984A>G p.R662G | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GLRA2 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- HR | c.1119del p.S374Afs*6 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- IDH3A | c.162del p.F54Lfs*26 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | called by mutect2, pindel, varscan2
- IGHG1 | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGHV2-5 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- IGLV1-40 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ISL1 | c.14del p.G5Efs*9 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | called by mutect2, pindel, varscan2
- ITGA7 | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- ITGAE | c.342del p.P115Lfs*57 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- ITGAX | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- ITGAX | c.3072dup p.A1025Cfs*9 | Frame Shift Ins (INS) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- KIR2DL1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 64/293 reads (22%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.94); called by muse, varscan2
- KRTAP10-11 | c.523del p.Q175Sfs*133 | Frame Shift Del (DEL) | VAF 34/181 reads (19%) | called by mutect2, pindel, varscan2
- LCE2D | c.31del p.Q11Sfs*63 | Frame Shift Del (DEL) | VAF 29/136 reads (21%) | called by mutect2, pindel*, varscan2
- LYZL4 | c.149dup p.A51Gfs*18 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- MRC1 | c.1883G>T p.W628L | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- MRC1 | c.1884G>T p.W628C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NMT1 | c.250_251dup p.L84Ffs*50 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- NOMO2 | c.862G>T p.G288C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.319); called by mutect2, varscan2
- OR2AT4 | c.92del p.P31Lfs*14 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- OR4D9 | c.364del p.R122Afs*3 | Frame Shift Del (DEL) | VAF 13/68 reads (19%) | called by mutect2, pindel, varscan2
- PASK | c.2413_2414del p.V805* | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by pindel, varscan2
- PLK3 | c.1011dup p.N338Qfs*4 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TBC1D3F | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by mutect2, varscan2
- TRBV5-1 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
233 further variants in this file (3 protein-altering or splice-affecting, 209 silent, 21 other) are not listed here.
